Surgical pathology report (de-identified scan), TCGA case TCGA-V5-A7RC, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Duke University, specimen TCGA-V5-A7RC-01B (Primary Tumor).

Patient

Primary

Surgical Pathology: Final

Surg Path

Surg Path:

ICD-0-3
Carcinoma, squamous cell NOS
Site: Esophagus, middle third C15.4
path Esophagus NOS C15.9

Collection Date:

Accession Date:

Pathology Number:

9/11/16/14

====CLINICAL HISTORY=====

ICD-9 CODE: 530.20, 787.20

Esophageal ulcer

===GROSS EXAMINATION===

A. "Esophageal ulcer", in formalin. Received are multiple white-pink
tissue fragments with an aggregate dimension of 0.8 x 0.5 x 0.2 cm.
In toto A1. FS:

===MICROSCOPIC EXAMINATION===

Microscopic examination is performed by Dr.

===DIAGNOSIS===

A. ESOPHAGEAL ULCER, ENDOSCOPIC BIOPSY:

INVASIVE SQUAMOUS CELL CARCINOMA.

NOTE: These findings are reported by telephone to Dr.

on Dr. has reviewed this case and concurs.

I certify that I personally evaluated this specimen and have made the above diagnosis.

Electronically signed:

Case come in with long met.

Source: NCI Genomic Data Commons file 05f02b03-1665-4f71-945d-b0f2b1b9da30 (TCGA-V5-A7RC.8CC9E5E8-D3B1-475E-B7BD-A6ACBE02B467.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).